Somatic mutation profile of tumor specimen TCGA-FY-A40K-01A (aliquot TCGA-FY-A40K-01A-11D-A23M-08) from TCGA case TCGA-FY-A40K, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 46.8 years (17,092 days).
Specimen TCGA-FY-A40K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c54dc33d-7793-4256-a315-3fea188c732f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A40K-10A (Blood Derived Normal), aliquot TCGA-FY-A40K-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/470226ad-82d4-4607-9289-56bb3403b4a5

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CD38 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56892072; called by muse, mutect2
- MMD2 | c.757G>A p.A253T (on ENST00000404774 / NM_001100600.2; = p.A229T on NM_198403.4) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV68660966; called by muse, mutect2, varscan2
- PRRC2A | c.1458T>G p.C486W | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100784581, COSV63224930; called by muse, mutect2, varscan2
- RTTN | c.6C>T p.V2= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs778293454, COSV55349502; called by muse, mutect2, varscan2
